Somatic mutation profile of tumor specimen TCGA-DX-A8BR-01A (aliquot TCGA-DX-A8BR-01A-11D-A417-09) from TCGA case TCGA-DX-A8BR, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 63.8 years (23,302 days).
Specimen TCGA-DX-A8BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b7899ff-6050-4201-96ee-800e90ef2e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BR-10B (Blood Derived Normal), aliquot TCGA-DX-A8BR-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe54ef74-32fb-4e8d-8bb0-74e19f72f2d6

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL6 | c.1340G>A p.R447Q (on ENST00000379240; = p.R472Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs779755365, COSV57299727; called by muse, mutect2, varscan2
- AHCTF1 | c.1341G>T p.M447I (on ENST00000366508; = p.M421I on NM_015446.5) | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100403111; called by muse, mutect2, varscan2
- ALDH9A1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100699273; called by muse, mutect2, varscan2
- ALPL | c.1420G>C p.V474L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100876157; called by muse, mutect2, varscan2
- BMS1 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100996460; called by muse, mutect2, varscan2
- CDH4 | c.2587G>T p.D863Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848427, COSV100848637; called by muse, mutect2, varscan2
- CFAP299 | c.354C>G p.D118E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100811350; called by muse, mutect2, varscan2
- CNPPD1 | c.118T>G p.Y40D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99811367; called by muse, mutect2, varscan2
- COPB2 | c.1587G>C p.W529C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300472; called by muse, mutect2, varscan2
- COPB2 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100300473; called by muse, mutect2, varscan2
- CRYBG1 | c.2294G>C p.R765T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.149); catalogued as COSV100954398; called by muse, mutect2, varscan2
- CRYBG1 | c.2857G>C p.V953L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV100954399; called by muse, mutect2, varscan2
- CRYBG1 | c.3191G>A p.G1064E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100954400; called by muse, mutect2, varscan2
- DNAH5 | c.8204C>T p.A2735V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV99445126; called by muse, mutect2, varscan2
- DNAI3 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99641371; called by muse, mutect2, varscan2
- DYRK4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99155375; called by muse, mutect2, varscan2
- H2AC6 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.23); catalogued as COSV100019743; called by muse, mutect2, varscan2
- HSP90AB1 | c.2113C>G p.P705A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs559392885, COSV99240880; called by muse, mutect2, varscan2
- ITIH5 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV99903739; called by muse, mutect2, varscan2
- LAMTOR1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV99194376; called by muse, mutect2, varscan2
- MYH11 | c.2998G>C p.E1000Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100257713, COSV55573301; called by muse, mutect2, varscan2
- MYL6 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99255059; called by muse, mutect2, varscan2
- NEURL1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs775661307, COSV100582993; called by muse, mutect2, varscan2
- OR1F1 | c.506G>C p.C169S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100484360; called by muse, mutect2, varscan2
- PIGB | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs768748995, COSV99380027; called by muse, mutect2, varscan2
- RUVBL2 | c.882+1G>T p.X294_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99668808; called by muse, mutect2, varscan2
- TENM3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 113/149 reads (76%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.253); catalogued as rs769986977, COSV101304885; called by muse, mutect2, varscan2
- TSPOAP1 | c.5536G>T p.E1846* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52104169, COSV99270070; called by muse, mutect2, varscan2
- VWA3B | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV101345938, COSV101346005; called by muse, mutect2
- ZNF711 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV99340636; called by muse, mutect2, varscan2
- COMMD1 | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- TMUB1 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.285); called by muse, mutect2
- USP44 | c.905del p.L302* | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ABI3 | c.387C>T p.N129= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99865219; called by muse, mutect2, varscan2
- AC006059.2 | c.1170G>A p.K390= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100045159; called by muse, mutect2, varscan2
- ASIC2 | c.390C>T p.D130= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1003082354, COSV100725736; called by muse, mutect2, varscan2
- HIRA | c.2688G>A p.S896= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs781832172, COSV54278551, COSV99601054; called by muse, mutect2
- KRT1 | c.1719C>T p.G573= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99358490; called by muse, mutect2, varscan2
- LAIR1 | c.807A>G p.P269= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100479429; called by muse, mutect2, varscan2
- MUC21 | c.876A>C p.T292= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100888823; called by muse, mutect2, varscan2
- PCDHA7 | c.156G>A p.L52= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1489443393, COSV100971240; called by muse, mutect2, varscan2
- PDE1C | c.1362C>T p.I454= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs564932801, COSV58528346; called by muse, mutect2, varscan2
- PRSS35 | c.1029G>A p.S343= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs757228644, COSV63800234; called by muse, mutect2, varscan2
- TKTL2 | c.1287A>T p.G429= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99761106; called by muse, mutect2
- MIR146A | n.95A>C | RNA (SNP) | VAF 12/32 reads (38%) | catalogued as rs953454916; called by muse, mutect2
